Gene-level copy-number profile of tumor specimen HTMCP-03-06-02113-01A from CGCI case HTMCP-03-06-02113, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02113-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 33fe9361-0fe9-4dc2-b8a0-0c4b88f5161c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02113-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/51629b54-0374-4402-9422-14020b252cb8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 324; copy number 2: 14,387; copy number 3: 28,454; copy number 4: 8,969; copy number 5: 4,630; copy number 6: 840; copy number 7: 34; copy number 8: 549; copy number 9: 127; copy number 11: 64; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–2): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr3:60,616,822–60,690,719, 3 genes (within-gene range 0–1): AC104164.2, MIR548BB, PPIAP70.
- chr6:32,517,353–32,589,848, 4 genes: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr17:46,274,784–46,487,141, 4 genes: ARL17B, LRRC37A, RN7SL656P, NSFP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 776 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,112,063, 41 genes, copy number 8: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635.
- chr5:1,201,595–45,895,970, 637 genes, copy number 8–11 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 7: TRGC2.
- chr7:38,257,879–38,340,998, 14 genes, copy number 7: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr14:18,333,726–18,650,966, 17 genes, copy number 8: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr14:21,950,406–22,490,553, 63 genes, copy number 7–9 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 9: TRAC.
- chr16:66,366,622–66,412,135, 2 genes, copy number 12: CDH5, LINC00920.

Autosomal genes at a single copy (total copy number 1): 324. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
